Somatic mutation profile of tumor specimen TCGA-16-0861-01A (aliquot TCGA-16-0861-01A-01W-0424-08) from TCGA case TCGA-16-0861, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.1 years (23,778 days).
Specimen TCGA-16-0861-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6efe148-56d8-4fdd-b577-7ed0e1a52318.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-16-0861-10A (Blood Derived Normal), aliquot TCGA-16-0861-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/830157d1-4b29-4766-ae58-9a4de26e3eff

The open-access MAF lists 71 somatic variants for this specimen: 57 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Frame Shift Ins 13, Silent 13, Nonsense Mutation 5, Splice Site 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 34/222 reads (15%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIGO | c.2361dup p.T788Hfs*5 | Frame Shift Ins (INS) | VAF 12/102 reads (12%) | catalogued as rs770591449; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.209+4_209+7del p.X70_splice | Splice Site (DEL) | VAF 10/18 reads (56%) | hotspot (GDC flag); catalogued as rs398123318; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCA13 | c.7643C>T p.T2548I | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV71292668; called by muse, mutect2
- ARHGAP28 | c.1905+2T>C p.X635_splice (on ENST00000383472 / NM_001366230.1; = p.X476_splice on NM_001010000.3) | Splice Site (SNP) | VAF 45/122 reads (37%) | catalogued as COSV51630838; called by muse, mutect2, varscan2
- AVPR1A | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs1321821927, COSV54545511; called by muse, mutect2, varscan2
- BIRC6 | c.13007G>A p.S4336N | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.258); catalogued as COSV70195106; called by muse, mutect2, varscan2
- BTRC | c.421T>G p.F141V (on ENST00000370187 / NM_033637.4; = p.F105V on NM_003939.5) | Missense Mutation (SNP) | VAF 157/201 reads (78%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as COSV64560326; called by muse, mutect2, varscan2
- CAND2 | c.2863dup p.V955Gfs*52 (on ENST00000456430 / NM_001162499.2; = p.V862Gfs*52 on NM_012298.3) | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | catalogued as rs780431641; called by pindel, varscan2
- CIDEA | c.458A>T p.E153V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57597126; called by muse, mutect2, varscan2
- DHX35 | c.451-2A>T p.X151_splice | Splice Site (SNP) | VAF 36/1170 reads (3%) | catalogued as COSV52668363; called by muse, mutect2
- DNAH5 | c.6332G>A p.R2111H | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs946204829, COSV54202034; called by muse, mutect2, varscan2
- DNAJC6 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54769123; called by muse, mutect2, varscan2
- EHD3 | c.400A>T p.N134Y | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59029095; called by muse, mutect2, varscan2
- EIF4G2 | c.2361dup p.S788Qfs*3 | Frame Shift Ins (INS) | VAF 12/111 reads (11%) | catalogued as rs781635731; called by mutect2, varscan2
- EMSY | c.228A>C p.L76F | Missense Mutation (SNP) | VAF 143/319 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58257018; called by muse, mutect2, varscan2
- F9 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 68/78 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM057674, CM057675, CM125298, COSV54378486; called by muse, mutect2, varscan2
- FAM219A | c.492dup p.K165Qfs*39 (on ENST00000445726; = p.K148Qfs*39 on NM_147202.2 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 13/98 reads (13%) | catalogued as rs760074479; called by mutect2, varscan2
- FANCE | c.929dup p.V311Sfs*2 | Frame Shift Ins (INS) | VAF 70/533 reads (13%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, varscan2
- FGA | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1283170104, COSV57392420; called by muse, mutect2, varscan2
- FLG | c.2410G>T p.E804* | Nonsense Mutation (SNP) | VAF 80/193 reads (41%) | catalogued as COSV64235891; called by muse, mutect2, varscan2
- FRYL | c.2851C>G p.L951V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51938400; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | catalogued as rs749150409; called by mutect2, varscan2
- GSS | c.1360A>T p.I454F | Missense Mutation (SNP) | VAF 738/2306 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.29); catalogued as COSV53622357; called by muse, mutect2, varscan2
- GUCY2D | c.1340C>G p.P447R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV54694268; called by muse, mutect2, varscan2
- GZMB | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 75/99 reads (76%) | catalogued as rs199605460, COSV53539818; called by muse, mutect2, varscan2
- HS3ST3A1 | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 80/350 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1344458516, COSV52372499; called by muse, mutect2, varscan2
- IARS1 | c.2900C>T p.A967V | Missense Mutation (SNP) | VAF 180/518 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV65112901; called by muse, mutect2, varscan2
- IARS1 | c.2899G>T p.A967S | Missense Mutation (SNP) | VAF 187/533 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100986734; called by muse, mutect2, varscan2
- INSR | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 99/207 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV57157020; called by muse, mutect2, varscan2
- IQUB | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs371332386; called by muse, mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 18/76 reads (24%) | catalogued as rs777328830; called by mutect2, varscan2
- ME1 | c.490T>A p.C164S | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV63837411; called by muse, mutect2
- NCAPH2 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55366096; called by muse, mutect2, varscan2
- NIN | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 260/352 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1442191019, COSV55379342; called by muse, mutect2, varscan2
- NPAP1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs780506627, COSV61503994; called by muse, mutect2, varscan2
- OSBPL2 | c.543dup p.I182Hfs*12 (on ENST00000313733 / NM_144498.4; = p.I170Hfs*12 on NM_014835.4) | Frame Shift Ins (INS) | VAF 29/230 reads (13%) | catalogued as rs780916980; called by mutect2, varscan2
- PCDHB15 | c.456T>G p.F152L | Missense Mutation (SNP) | VAF 209/534 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.168); catalogued as COSV50858111; called by muse, mutect2, varscan2
- PDS5B | c.2812G>C p.E938Q | Missense Mutation (SNP) | VAF 130/330 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.768); catalogued as COSV59722886; called by muse, mutect2, varscan2
- PFKP | c.1785dup p.L596Afs*6 | Frame Shift Ins (INS) | VAF 9/70 reads (13%) | catalogued as rs747416036; called by mutect2, varscan2
- RAB11B | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs754522300, COSV60085170; called by muse, mutect2, varscan2
- RASGEF1C | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV63177103; called by muse, mutect2, varscan2
- RERG | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 138/176 reads (78%) | catalogued as COSV56999753; called by muse, mutect2, varscan2
- SAMD9 | c.2720G>T p.G907V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV66072765; called by muse, mutect2
- SLC9A5 | c.1228dup p.A410Gfs*12 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | catalogued as rs35182421; called by mutect2, pindel
- SUSD1 | c.1349C>A p.T450K | Missense Mutation (SNP) | VAF 126/248 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62582070; called by muse, mutect2, varscan2
- SYT1 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 170/386 reads (44%) | catalogued as COSV54031457; called by muse, mutect2, varscan2
- TAGLN3 | c.141dup p.G48Rfs*21 | Frame Shift Ins (INS) | VAF 6/51 reads (12%) | catalogued as rs762583525; called by pindel, varscan2
- TTN | c.63467C>T p.P21156L (on ENST00000591111; = p.P13732L on NM_003319.4) | Missense Mutation (SNP) | VAF 162/415 reads (39%) | PolyPhen probably damaging (0.917); catalogued as rs1371471381, COSV100597244, COSV59869160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VAV3 | c.304G>T p.V102F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64064684; called by muse, mutect2, varscan2
- WDR6 | c.2421dup p.R808Afs*3 | Frame Shift Ins (INS) | VAF 14/54 reads (26%) | catalogued as rs750038548; called by mutect2, varscan2
- WNK1 | c.5441C>T p.A1814V (on ENST00000315939 / NM_018979.4; = p.A1567V on NM_014823.3) | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs953160606, COSV60024998; called by muse, mutect2
- ZNF527 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1276546322, COSV62229340; called by muse, mutect2, varscan2
- ZNF608 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 257/655 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1008720444, COSV60434966; called by muse, mutect2, varscan2
- ARV1 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 10/261 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- LRP2 | c.4178A>T p.E1393V | Missense Mutation (SNP) | VAF 16/522 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SORCS1 | c.2777G>A p.W926* | Nonsense Mutation (SNP) | VAF 26/349 reads (7%) | called by muse, mutect2
- ATP11C | c.1830T>C p.D610= | Silent (SNP) | VAF 132/179 reads (74%) | catalogued as COSV59559069; called by muse, mutect2, varscan2
- ATXN2L | c.1830A>T p.P610= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV57364766; called by muse, mutect2, varscan2
- DLEC1 | c.2457T>C p.F819= | Silent (SNP) | VAF 105/310 reads (34%) | catalogued as COSV57294676; called by muse, mutect2, varscan2
- DSC1 | c.462C>T p.H154= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as rs1196619139, COSV57141302; called by muse, mutect2, varscan2
- DST | c.20631C>T p.G6877= (on ENST00000361203 / NM_001374722.1; = p.G4574= on NM_015548.5) | Silent (SNP) | VAF 457/1183 reads (39%) | catalogued as rs760689511, COSV54995946; called by muse, mutect2, varscan2
- HIPK2 | c.93G>A p.L31= | Silent (SNP) | VAF 60/1322 reads (5%) | catalogued as rs931528143, COSV61225292; called by muse, mutect2
- LRP1B | c.1986A>T p.T662= | Silent (SNP) | VAF 14/434 reads (3%) | catalogued as COSV67243936; called by muse, mutect2
- LY75 | c.2076T>C p.D692= | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as COSV55101574; called by muse, mutect2, varscan2
- PPP4R3A | c.687T>C p.A229= | Silent (SNP) | VAF 33/39 reads (85%) | catalogued as COSV61503361; called by muse, mutect2, varscan2
- PTPRN | c.2616C>T p.F872= | Silent (SNP) | VAF 56/153 reads (37%) | catalogued as COSV55345341; called by muse, mutect2, varscan2
- SEMA3C | c.633T>C p.D211= | Silent (SNP) | VAF 3/51 reads (6%) | called by muse, mutect2
- SV2B | c.1308C>T p.Y436= | Silent (SNP) | VAF 279/877 reads (32%) | catalogued as rs140230861; called by muse, mutect2, varscan2
- TUBA3D | c.540C>T p.A180= | Silent (SNP) | VAF 125/361 reads (35%) | catalogued as rs544741714, COSV58310648; called by muse, mutect2, varscan2
- SV2C | c.581-20769G>A | Intron (SNP) | VAF 30/55 reads (55%) | catalogued as rs878875446, COSV59213582; called by muse, mutect2, varscan2
